Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A217, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A217-01A (Primary Tumor).

[page 1 of 2]
103-0-3
Carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 per 4/8/11

SURGICAL PATHOLOGY

Case Number :

Diagnosis:

Liver, segment 3, partial hepatectomy

- Hepatocellular carcinoma, grade 3 (Edmondson and Steiner classification) ✓

- Tumor size: 7.4 cm

- Margins: negative for tumor

- Capsule involvement: not identified

- Lymphovascular space invasion identified (A4)

- Background liver: steatosis affecting approximately 5% of liver parenchyma

- AJCC pathologic stage: pT2 pNx

Clinical History:

65-year-old female with HCC.

Gross Description:

Received is one appropriately labeled container, additionally labeled "resection

Segment 3." It holds a 235.4 gram, 11 x 10 x 7.5 cm partial hepatectomy

specimen. The specimen is partially covered with a smooth, red/tan capsule with

focal hemorrhagic fibrofatty adhesions. The parenchymal margin is marked with

blue ink and the specimen is sectioned to reveal a 7.4 x 6.1 x 4.9 cm well

circumscribed fleshy lobulated mass with focal areas of hemorrhage. The mass is

located beneath the capsule and focally abuts the blue inked parenchymal margin.

The surrounding hepatic parenchyma is tan/brown with focal induration and

discoloration along one edge of the tumor.

Tumor and normal are given to Tissue Procurement.

Block summary:

A1 - discolored edge of hepatic parenchyma adjacent to tumor

A2 - tumor and overlying capsule

[page 2 of 2]
A3 - tumor in relationship to blue inked parenchymal margin
A4 - tumor and parenchyma
A5 - tumor and capsule
A6-A8 - additional sections from tumor

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Attending Pathologist: , MD

I have personally conducted the evaluation of the above
specimens and have
rendered the above diagnosis(es).

Electronically Signed by:, MD

Date

Source: NCI Genomic Data Commons file a4f9601e-eaba-4511-a2fd-2ae62e9a6557 (TCGA-BC-A217.FEA652A1-DD1E-4D78-87DF-FC2162267A96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).